CCDI case PBBUMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified parts of mouth.
https://portal.gdc.cancer.gov/cases/fef096e6-9c7a-4a70-9be9-03312fdcdd85

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Mucoepidermoid carcinoma: ICD-O-3 morphology code: 8430/3; Tissue or organ of origin: Submandibular gland; Age at diagnosis: 15.6 years (5,694 days).

Biospecimens (3 samples)
- Sample 0DHQDF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHQEL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJ6K8: Tissue type: Tumor; Specimen type: Solid Tissue.
